Surgical pathology report (de-identified scan), TCGA case TCGA-D8-A27W, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D8-A27W-01A (Primary Tumor).

1CD-0-3
carcinoma, mucinous 8480/3
site: breast, NOS C50.9

hw 5/19/11

page 1 / 1

original

Examination: Histopathological examination

Internal invoice No.

Value of diagnostic procedure

Examination No.:

Patient:

PESEL:

Age:

Gender: F

Material: **Total organ resection – right breast with axillary tissues**

Unit in charge:

Physician in charge:

Material collected on:

Material received on:

Expected time of examination: **up to 8 working days**

Clinical diagnosis: **Right breast with an ulcerous tumour and right axillary lymph nodes**

Reviewed on:	hw 5/19/11	5/19/11

Examination performed on:

Results of immunohistochemical examination:

Estrogen receptors found in over 75% of neoplastic cell nuclei.

Progesterone receptors found in less than 10% of neoplastic cell nuclei.

HER2 protein stained with Ventana's Pathway HER-2/neu (4B5) Rabbit Monoclonal Antibody. Score=2+, FISH verification recommended.

Compliance validated by:

Examination performed on:

Macroscopic description:

Right breast sized 21.3 x 17.8 x 6.2 cm removed along with axillary tissues sized 9 x 8 x 3 cm and a skin flap of 18.7 x 8.2 cm. Weight 1040 g.

Tumour sized 5.3 x 3.8 x 5.3 cm in the middle part, located 2.2 cm from the lower boundary, 1.1 cm from the base and 0 cm from the skin.

Microscopic description:

Carcinoma mucinosum invasivum - NHG3 (3 + 3 +2: 10 mitoses/10 HPF - visual area: 0.55mm).

Infiltratio carcinomatosa cutis mammae.

Glandular texture showing parenchymal atrophy.

AXILLARY LYMPH NODES:

Lymphonodulitis chronica (No XII).

Histopathological Diagnosis:

Carcinoma mucinosum invasivum mammae dextrae (NHG3, pT4b, pNO). Invasive mucinous carcinoma of the right breast.

Compliance validated by:

Source: NCI Genomic Data Commons file 48f5de95-d4a7-46be-a2be-b797c5b70a5a (TCGA-D8-A27W.292571E3-D500-4337-B435-834B504F3109.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).